Gene-level copy-number profile of tumor specimen TCGA-VQ-AA6F-01A from TCGA case TCGA-VQ-AA6F, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 58.0 years (21,170 days).
Specimen TCGA-VQ-AA6F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f318ada4-7abd-43e6-a346-a4dfd041a7aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA6F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2376dcf3-e3a5-4d7b-baa3-7cef430e9e33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 21,291; copy number 2: 25,921; copy number 3: 11,019; copy number 4: 813; copy number 5: 153; copy number 6: 418; copy number 9: 13; copy number 11: 73; copy number 13: 37; copy number 18: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA6F-01A-31D-A40Z-01): tumor purity 0.34, ploidy 1.6, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,032,884–186,509,361, 7 genes (within-gene range 0–2): LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1.
- chr2:234,952,017–236,294,927, 15 genes (within-gene range 0–2): SH3BP4, AC114814.1, CEP19P1, AC114814.2, AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P, Y_RNA, GBX2, AC019068.1, ASB18, RNU1-31P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 745 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,596,393–143,177,617, 18 genes, copy number 5 (within-gene range 3–5): PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1.
- chr3:143,313,067–143,518,229, 5 genes, copy number 5: AC131210.1, SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15.
- chr6:70,216,040–76,092,940, 107 genes, copy number 5 (broad region; genes not listed).
- chr7:67,627,831–72,828,200, 36 genes, copy number 6 (within-gene range 4–6): MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75, CALN1, RNA5SP232, AC005011.1, ABCF2P2, TYW1B, MIR4650-2, AC211469.2, AC211469.1.
- chr7:83,355,154–94,431,227, 134 genes, copy number 5–18 (within-gene range 3–18) (broad region; genes not listed).
- chr9:31,165,618–43,045,120, 382 genes, copy number 6 (broad region; genes not listed).
- chr19:22,665,552–24,163,425, 63 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,992. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
